Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A7R2, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A7R2-01A (Primary Tumor).

[Redacted]

[Redacted]

ICD-O-3
Astrocytoma, grade III
C84.1 9401/3
Site: Brain, supratentorial NDS
path C71.0
Brain, NDS C71.9
QW 9/27/13

Anaplastic astrocytoma WHO grade III

Untranslated original report
is housed at the BCR.

[Redacted]

Source: NCI Genomic Data Commons file 77da62ab-b066-47f1-90f8-b4d16a23f026 (TCGA-S9-A7R2.2907EB1D-32CC-4BB7-B485-AFF04CA01E7F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).